Somatic mutation profile of tumor specimen TCGA-FD-A5BR-01A (aliquot TCGA-FD-A5BR-01A-11D-A26M-08) from TCGA case TCGA-FD-A5BR, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 57.4 years (20,964 days).
Specimen TCGA-FD-A5BR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6c38db1b-22c8-420b-a2b0-2f1311ba87e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A5BR-10A (Blood Derived Normal), aliquot TCGA-FD-A5BR-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3d73713f-f1fb-4387-b966-8003ccf0989c

The open-access MAF lists 93 somatic variants for this specimen: 71 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, Silent 19, Frame Shift Del 6, Nonsense Mutation 2, 3'UTR 1, 5'UTR 1, Intron 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY8 | c.2188C>G p.Q730E | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.366); catalogued as COSV53911405, COSV53921965; called by muse, mutect2, varscan2
- ADGRF5 | c.3485G>T p.C1162F | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51938495; called by muse, mutect2, varscan2
- APOL2 | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as COSV50772757; called by muse, mutect2, varscan2
- ATP10A | c.2009A>T p.Y670F | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV63521882; called by muse, mutect2, varscan2
- BUB1 | c.1342A>G p.M448V | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.32); PolyPhen benign (0.009); catalogued as COSV57066187; called by muse, mutect2, varscan2
- C11orf16 | c.1201C>A p.P401T | Missense Mutation (SNP) | VAF 30/54 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV58168740; called by muse, mutect2, varscan2
- CATSPER2 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.157); catalogued as COSV58661621; called by muse, mutect2, varscan2
- CCDC30 | c.1711A>T p.K571* (on ENST00000340612; = p.K528* on NM_001080850.3) | Nonsense Mutation (SNP) | VAF 5/49 reads (10%) | catalogued as COSV100501473; called by muse, mutect2
- CDH13 | c.1304C>A p.S435Y | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV51857086, COSV99222076; called by muse, mutect2, varscan2
- CIT | c.5236A>G p.I1746V | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV55879121; called by muse, mutect2, varscan2
- CLIP1 | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56806917; called by muse, mutect2, varscan2
- CNTN2 | c.2027C>A p.T676N | Missense Mutation (SNP) | VAF 41/129 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.009); catalogued as rs373478324; called by muse, mutect2, varscan2
- CPZ | c.945C>A p.N315K (on ENST00000360986 / NM_001014447.3; = p.N304K on NM_003652.3) | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV59925074; called by muse, mutect2, varscan2
- DISP1 | c.3845A>G p.Y1282C | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52663551; called by muse, mutect2
- ERICH3 | c.3013C>T p.R1005W | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV100445851, COSV58614962; called by muse, mutect2, varscan2
- ERICH3 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV58614971; called by muse, mutect2, varscan2
- ETV1 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.731); catalogued as rs1326846768, COSV54137644; called by muse, mutect2, varscan2
- FBN2 | c.7613C>A p.T2538K | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.346); catalogued as COSV52536969; called by muse, mutect2
- FLG | c.11968G>A p.G3990R | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.41); PolyPhen benign (0.033); catalogued as rs370643935; called by muse, mutect2, varscan2
- FLG2 | c.5701C>T p.H1901Y | Missense Mutation (SNP) | VAF 75/251 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.041); catalogued as COSV66171429, COSV66171753; called by muse, mutect2, varscan2
- FMOD | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as COSV100724649, COSV61610491; called by muse, mutect2, varscan2
- GALP | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV62000872; called by muse, mutect2, varscan2
- GRIP1 | c.2626G>C p.A876P (on ENST00000359742 / NM_001379345.1; = p.A824P on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/153 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as COSV99670011; called by muse, mutect2
- HIVEP1 | c.6564T>A p.N2188K | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.936); catalogued as COSV65104186; called by muse, mutect2, varscan2
- HOOK2 | c.2045G>A p.R682Q | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as rs776777069, COSV50369051; called by muse, mutect2, varscan2
- IRF7 | c.1290C>A p.F430L (on ENST00000397566; = p.F417L on NM_001572.5) | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52760491; called by muse, mutect2, varscan2
- KIAA1614 | c.3166C>A p.P1056T | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs767663390, COSV62551557; called by muse, mutect2, varscan2
- MARK2 | c.2331del p.N777Kfs*6 (on ENST00000402010 / NM_001039469.2; = p.N713Kfs*6 on NM_004954.5) | Frame Shift Del (DEL) | VAF 29/119 reads (24%) | catalogued as COSV56851125; called by mutect2, pindel, varscan2
- MATN3 | c.1174G>A p.D392N | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.01); catalogued as COSV101337455; called by muse, mutect2
- MDGA2 | c.1669G>T p.D557Y (on ENST00000399232 / NM_001113498.2; = p.D259Y on NM_182830.4) | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62109600; called by muse, mutect2, varscan2
- MED13 | c.6310G>A p.V2104M | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101181107, COSV67266178; called by muse, mutect2, varscan2
- MPHOSPH9 | c.670G>T p.V224F | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT tolerated (0.52); PolyPhen benign (0.188); catalogued as COSV56623390; called by muse, mutect2, varscan2
- MTDH | c.1238T>G p.L413R | Missense Mutation (SNP) | VAF 31/341 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.025); catalogued as COSV60346005; called by muse, mutect2
- MUC16 | c.42400G>C p.E14134Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.974); catalogued as COSV66695583; called by muse, mutect2, varscan2
- MYH4 | c.3176_3179del p.L1059Rfs*4 | Frame Shift Del (DEL) | VAF 36/78 reads (46%) | catalogued as COSV55124026; called by mutect2, pindel, varscan2
- MYO9B | c.5041T>C p.C1681R | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV68282001; called by muse, mutect2, varscan2
- NEB | c.19273C>T p.R6425W | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs200165006; called by muse, mutect2
- NLGN1 | c.611T>G p.I204S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64343317; called by muse, mutect2, varscan2
- NXF1 | c.14G>C p.G5A | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.149); catalogued as COSV53675860; called by muse, mutect2, varscan2
- OPA1 | c.898A>T p.K300* (on ENST00000361510 / NM_130837.3; = p.K245* on NM_015560.3) | Nonsense Mutation (SNP) | VAF 15/71 reads (21%) | catalogued as CM014006, COSV100655371; called by muse, mutect2, varscan2
- PCLO | c.5430C>A p.D1810E | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV61658080; called by muse, mutect2, varscan2
- PIWIL2 | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV63253492; called by muse, mutect2, varscan2
- PRDM9 | c.176A>C p.N59T | Missense Mutation (SNP) | VAF 67/158 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.266); catalogued as COSV57011258, COSV99689739; called by muse, mutect2, varscan2
- PREX2 | c.630C>A p.N210K | Missense Mutation (SNP) | VAF 6/140 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV55793976, COSV55803000; called by muse, mutect2
- PSIP1 | c.1420+2T>C p.X474_splice | Splice Site (SNP) | VAF 24/72 reads (33%) | catalogued as COSV66255462; called by muse, varscan2
- PXDN | c.2390_2405del p.L797Rfs*17 | Frame Shift Del (DEL) | VAF 27/82 reads (33%) | catalogued as COSV53243648; called by mutect2, pindel, varscan2
- RAB31 | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.238); catalogued as COSV71262197, COSV71262267; called by muse, mutect2, varscan2
- RASAL3 | c.2311G>C p.A771P | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54613469, COSV99653431; called by muse, mutect2
- REG1A | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.193); catalogued as COSV52071032; called by muse, mutect2, varscan2
- SACS | c.10384C>A p.L3462I | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66545390; called by muse, mutect2
- SLC12A2 | c.1799C>T p.T600I | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV52475080; called by muse, varscan2
- SLC12A2 | c.1998C>G p.I666M | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52475092; called by muse, mutect2
- SLC12A2 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV99321271; called by muse, mutect2
- SLC22A2 | c.34G>A p.G12R | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.078); catalogued as rs200254093, COSV65267493; called by muse, mutect2, varscan2
- SLC27A2 | c.1484C>T p.T495I | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV51061659; called by muse, mutect2, varscan2
- SLC6A1 | c.548C>T p.T183I | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.782); catalogued as COSV55115665, COSV55118008; called by muse, mutect2, varscan2
- SPTA1 | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs201519091, COSV63750201, COSV63750984; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SULF1 | c.850C>A p.Q284K | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV52690085; called by muse, mutect2
- TBC1D13 | c.94A>C p.S32R | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV56355488; called by muse, mutect2, varscan2
- TBL3 | c.890A>C p.H297P | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.451); catalogued as COSV60342678; called by muse, mutect2, varscan2
- TMEM132B | c.1702G>A p.A568T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as rs550549644, COSV54751336; called by muse, mutect2, varscan2
- TMEM132B | c.1703C>A p.A568D | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV54765317; called by muse, mutect2, varscan2
- TMEM9B | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV58428033; called by muse, mutect2, varscan2
- UTP20 | c.6157C>G p.L2053V | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); catalogued as COSV55383328; called by muse, mutect2, varscan2
- ZKSCAN5 | c.503A>T p.D168V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV58744146; called by muse, mutect2, varscan2
- ZNF768 | c.1489T>C p.S497P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV63323691; called by muse, mutect2, varscan2
- DTWD1 | c.253C>G p.P85A | Missense Mutation (SNP) | VAF 2/10 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYH6 | c.2476del p.V826Sfs*7 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- OR2S2 | c.847del p.L283Ffs*6 | Frame Shift Del (DEL) | VAF 34/85 reads (40%) | called by mutect2, pindel, varscan2
- TBC1D20 | c.1177_1187del p.W393Vfs*20 | Frame Shift Del (DEL) | VAF 18/130 reads (14%) | called by mutect2, pindel, varscan2
- TP53 | c.1005_1010del p.E336_R337del | In Frame Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, pindel, varscan2
- ANKRD11 | c.5709C>T p.L1903= | Silent (SNP) | VAF 36/97 reads (37%) | catalogued as COSV56368812; called by muse, mutect2, varscan2
- CLPTM1L | c.1392G>T p.L464= | Silent (SNP) | VAF 14/159 reads (9%) | catalogued as COSV57992202; called by muse, mutect2
- COL6A3 | c.5418C>T p.S1806= | Silent (SNP) | VAF 24/111 reads (22%) | catalogued as rs398124123, COSV55085039; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DTWD1 | c.27C>G p.L9= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV52072540; called by muse, varscan2
- FLG | c.3036T>G p.T1012= | Silent (SNP) | VAF 178/542 reads (33%) | catalogued as COSV64246394; called by muse, mutect2, varscan2
- FRG2 | c.459T>C p.T153= | Silent (SNP) | VAF 50/190 reads (26%) | called by muse, mutect2, varscan2
- HNF1B | c.736T>C p.L246= | Silent (SNP) | VAF 20/145 reads (14%) | called by muse, mutect2, varscan2
- LONP2 | c.2298C>A p.A766= | Silent (SNP) | VAF 39/130 reads (30%) | catalogued as COSV53524958; called by muse, mutect2, varscan2
- LPA | c.4059G>A p.V1353= | Silent (SNP) | VAF 18/103 reads (17%) | catalogued as rs185035693, COSV60308742; called by muse, mutect2, varscan2
- MGAT2 | c.1290G>T p.G430= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs144122741, COSV53566814; called by muse, mutect2, varscan2
- MIDN | c.1308C>T p.G436= | Silent (SNP) | VAF 29/104 reads (28%) | catalogued as COSV56296500; called by muse, mutect2, varscan2
- MMD2 | c.504A>C p.A168= | Silent (SNP) | VAF 24/117 reads (21%) | catalogued as COSV68661386; called by muse, mutect2, varscan2
- MVD | c.798C>G p.T266= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV99880014; called by muse, mutect2
- OR2S2 | c.849T>C p.L283= | Silent (SNP) | VAF 38/76 reads (50%) | catalogued as COSV59530937; called by mutect2, varscan2
- PCDHGA5 | c.1560C>T p.F520= | Silent (SNP) | VAF 16/250 reads (6%) | catalogued as rs780121604, COSV53892863; called by muse, mutect2
- RAD21 | c.66T>C p.H22= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV52062489, COSV99815795; called by muse, mutect2
- TAF5 | c.534C>A p.A178= | Silent (SNP) | VAF 3/41 reads (7%) | catalogued as COSV100674713; called by muse, mutect2
- TENT4A | c.1161C>T p.F387= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV50098717; called by muse, mutect2, varscan2
- WRN | c.4107C>A p.V1369= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53305251; called by muse, mutect2, varscan2
- DST | c.4297-4132G>C | Intron (SNP) | VAF 32/101 reads (32%) | catalogued as COSV55033560; called by muse, mutect2, varscan2
- KLC4 | c.-1G>A | 5'UTR (SNP) | VAF 10/113 reads (9%) | catalogued as rs894624517, COSV52438426; called by muse, mutect2
- POMGNT1 | c.*346C>T | 3'UTR (SNP) | VAF 6/62 reads (10%) | catalogued as rs762671303, COSV100915682, COSV100915687; called by muse, mutect2
